MMRF case MMRF_1820 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0f2a444b-c250-46e3-a663-270665009a39

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 49 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 49.7 years (18,153 days); ISS stage: II; Days to last known disease status: 1,082 days (3.0 years); Days to last follow up: 1,082 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 29 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 43 days; Days to treatment end: 57 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 64 days; Days to treatment end: 77 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 85 days; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 138 days; Days to treatment end: 138 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 164 days; Days to treatment end: 179 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 193 days; Days to treatment end: 193 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -20 (ECOG 0): M Protein 3.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 127 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.92 mg/dL; Immunoglobulin G 51.1 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 4.8 µg/mL; Hemoglobin 5.27 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L.
- Day 85 (ECOG 1): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 9.05 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 3.2 µg/mL; Hemoglobin 6.45 mmol/L; Leukocytes 10.8 ×10⁹/L; Absolute Neutrophil 7.8 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 5.8 g/dL; Glucose 4.51 mmol/L.
- Day 162 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Beta 2 Microglobulin 2.57 µg/mL; Hemoglobin 6.39 mmol/L; Leukocytes 5.94 ×10⁹/L; Absolute Neutrophil 4.98 ×10⁹/L; Platelets 374 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 34 g/L; Total Protein 6.5 g/dL; Glucose 6.27 mmol/L.
- Day 253 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 6.5 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 3.28 µg/mL; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 5.27 ×10⁹/L; Absolute Neutrophil 2.96 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 6.1 g/dL; Glucose 4.9 mmol/L.
- Day 353 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.67 mg/dL; Immunoglobulin G 8.57 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.43 g/L; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 5.13 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 5.01 mmol/L.
- Day 407 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.86 mg/dL; Immunoglobulin G 8.62 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.64 g/L; Beta 2 Microglobulin 3.15 µg/mL; Lactate Dehydrogenase 1.43 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 3.43 ×10⁹/L; Absolute Neutrophil 1.72 ×10⁹/L; Platelets 114 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 6.8 g/dL; Glucose 4.13 mmol/L.
- Day 491 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 9.04 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 1.29 g/L; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 4.62 mmol/L.
- Day 610 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.45 mg/dL; Immunoglobulin G 9.54 g/L; Immunoglobulin A 0.58 g/L; Immunoglobulin M 0.62 g/L; Hemoglobin 9.05 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 7.4 g/dL; Glucose 5.28 mmol/L.
- Day 708 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.77 mg/dL; Immunoglobulin G 8.18 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.36 g/L; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 6.3 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.35 mmol/L; Albumin 48 g/L; Total Protein 7 g/dL; Glucose 5.23 mmol/L.
- Day 799 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.86 mg/dL; Immunoglobulin G 7.68 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.43 mmol/L; Albumin 45 g/L; Total Protein 6.8 g/dL; Glucose 4.73 mmol/L.
- Day 883 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.84 mg/dL; Immunoglobulin G 7.81 g/L; Immunoglobulin A 0.8 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.4 mmol/L; Albumin 45 g/L; Total Protein 6.9 g/dL; Glucose 5.67 mmol/L.
- Day 963 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Immunoglobulin G 7.62 g/L; Immunoglobulin A 0.8 g/L; Immunoglobulin M 0.59 g/L; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 45 g/L; Total Protein 6.8 g/dL; Glucose 5.12 mmol/L.
- Day 1,082 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.76 mg/dL; Immunoglobulin G 7.84 g/L; Immunoglobulin A 0.95 g/L; Immunoglobulin M 0.5 g/L; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 9.42 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.5 mmol/L; Albumin 49 g/L; Total Protein 7.1 g/dL; Glucose 4.9 mmol/L.

Other clinical attributes
- Day -20: Weight: 65 kg; Height: 167 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1820_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -20 days.
- Sample MMRF_1820_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -20 days.
